Gene-level copy-number profile of tumor specimen ALCH-AESK-TTP1-A from ALCHEMIST case ALCH-AESK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,192 days).
Specimen ALCH-AESK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fa7ed14a-502f-4d63-81ef-32ec9a660c2c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AESK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/d7282ed8-e227-4ce2-b338-3088dfac649e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 3,990; copy number 2: 51,667; copy number 3: 3,043; copy number 4: 188; copy number 5: 7; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,616,836–10,617,115, 1 gene (within-gene range 0–2): RN7SL614P.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–2): AL139423.1.
- chr3:50,558,025–50,649,291, 5 genes: C3orf18, HEMK1, AC096920.1, CISH, MAPKAPK3.
- chr5:176,880,869–176,899,346, 1 gene (within-gene range 0–2): HK3.
- chr9:93,318,199–93,346,414, 1 gene (within-gene range 0–2): C9orf129.
- chr11:70,705,167–70,706,068, 2 genes (within-gene range 0–2): Y_RNA, AP000590.1.
- chr12:131,292,068–131,299,751, 4 genes: RPS6P20, AC092850.1, LINC02415, RNA5SP376.
- chr19:18,929,201–18,947,452, 2 genes (within-gene range 0–2): HOMER3, HOMER3-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,906,196–248,937,043, 3 genes, copy number 5: PGBD2, RNU6-1205P, RPL23AP25.
- chr3:171,941,607–171,996,871, 1 gene, copy number 5: AC055714.1.
- chr6:34,279,679–34,426,071, 2 genes, copy number 5 (within-gene range 1–5): NUDT3, RPS10-NUDT3.
- chr11:117,135,528–117,138,582, 1 gene, copy number 7: AP005018.2.
- chr17:59,674,636–59,707,626, 1 gene, copy number 5 (within-gene range 2–5): PTRH2.

Autosomal genes at a single copy (total copy number 1): 1,143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
